Somatic mutation profile of tumor specimen TCGA-61-1741-01A (aliquot TCGA-61-1741-01A-02W-0639-09) from TCGA case TCGA-61-1741, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 76.0 years (27,762 days).
Specimen TCGA-61-1741-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1784c0fb-3536-4b31-9b96-1d2c8e9b8e54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1741-11A (Solid Tissue Normal), aliquot TCGA-61-1741-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e010aa4b-f219-461a-aa4c-4e57c5dca941

The open-access MAF lists 34 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1422-4_1428del p.X474_splice | Splice Site (DEL) | VAF 23/29 reads (79%) | hotspot (GDC flag); called by pindel, varscan2
- TP53 | c.710T>A p.M237K | Missense Mutation (SNP) | VAF 83/94 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765848205, COSV52682586, COSV53017093, COSV53037559, COSV53037741; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BPIFB3 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1475004418, COSV100972335; called by muse, mutect2, varscan2
- CLCN6 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as rs143362803; called by muse, mutect2, varscan2
- CSPG4 | c.4992dup p.E1665Rfs*8 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | catalogued as rs757248830; called by mutect2, pindel
- CYP51A1 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1342063694, COSV50152580; called by muse, mutect2, varscan2
- DAXX | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 70/185 reads (38%) | catalogued as rs1213838920, COSV56471089; called by mutect2, varscan2
- DIO3 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1272919729, COSV63773300; called by muse, mutect2, varscan2
- EPC1 | c.851C>G p.S284C | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV53927589; called by muse, mutect2, varscan2
- FBXO39 | c.411C>A p.D137E | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100386171; called by muse, mutect2
- FSHR | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1296443148, COSV58628271; called by muse, mutect2, varscan2
- GLS2 | c.1127C>T p.T376I | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150956694; called by muse, mutect2, varscan2
- ID3 | c.301-1G>T p.X101_splice | Splice Site (SNP) | VAF 13/57 reads (23%) | catalogued as COSV101000757, COSV65800822; called by muse, mutect2
- KIF17 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.169); catalogued as rs146714930; called by muse, mutect2, varscan2
- LILRA4 | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52493355; called by mutect2, varscan2
- LRRTM1 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54443994; called by muse, mutect2, varscan2
- MDN1 | c.12876C>A p.H4292Q | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV65524792; called by muse, mutect2, varscan2
- NPC1L1 | c.1063A>G p.I355V | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56927280; called by muse, mutect2, varscan2
- PCDH19 | c.3361G>T p.V1121F (on ENST00000373034 / NM_001184880.2; = p.V1073F on NM_020766.3) | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.12); catalogued as COSV55266734, COSV99720594; called by muse, mutect2, varscan2
- PCDHA6 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.366); catalogued as COSV100972215, COSV100972507; called by muse, mutect2
- PIK3R5 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs748006348, COSV99353168; called by mutect2, varscan2
- PTER | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100126617; called by muse, mutect2
- TFRC | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373123870; called by muse, mutect2
- UCP3 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58368763, COSV58369032; called by muse, mutect2, varscan2
- EP300 | c.6910_6911del p.S2304Qfs*74 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by pindel, varscan2
- GALP | c.15dup p.V6Rfs*33 | Frame Shift Ins (INS) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- SMC3 | c.2437_2438del p.Q813Vfs*4 | Frame Shift Del (DEL) | VAF 44/118 reads (37%) | called by mutect2, pindel, varscan2
- SULF1 | c.1910_1925del p.R637Ifs*19 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel
- COL4A2 | c.3060A>G p.S1020= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV64630634; called by muse, mutect2, varscan2
- DPH5 | c.645G>A p.E215= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as COSV59859858; called by muse, mutect2, varscan2
- DSTN | c.166T>C p.L56= | Silent (SNP) | VAF 67/123 reads (54%) | catalogued as rs943290710, COSV55713502; called by muse, mutect2, varscan2
- POLA1 | c.2904C>T p.Y968= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as rs1301073134, COSV66883268; called by muse, mutect2, varscan2
- PRPF6 | c.270A>C p.S90= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV99411798; called by muse, mutect2
- SUMF2 | c.733+264dup | Intron (INS) | VAF 10/34 reads (29%) | catalogued as rs776978621; called by mutect2, varscan2
